Somatic mutation profile of tumor specimen TCGA-AR-A2LQ-01A (aliquot TCGA-AR-A2LQ-01A-22D-A18P-09) from TCGA case TCGA-AR-A2LQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.9 years (21,865 days).
Specimen TCGA-AR-A2LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1675c07-6ab7-4b3e-a70d-296d4dbb0e63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LQ-10A (Blood Derived Normal), aliquot TCGA-AR-A2LQ-10A-01D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58455cbb-a81c-40aa-a851-719b4794e16a

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPF | c.1531A>G p.N511D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100871504; called by muse, mutect2
- ESS2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs780144981, COSV52817144; called by muse, mutect2, varscan2
- FMOD | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.292); catalogued as COSV100724496, COSV61610106; called by muse, mutect2
- KCNC1 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99788778; called by muse, mutect2
- PCDHB1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1554267411, COSV100128032; called by muse, mutect2
- YTHDC1 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.99); catalogued as COSV60008866; called by muse, mutect2, varscan2
- PLEKHG1 | c.108A>C p.S36= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100651467; called by muse, mutect2
- USP22 | c.912G>T p.G304= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99820088; called by muse, mutect2
